Surgical pathology report (de-identified scan), TCGA case TCGA-W3-AA1R, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  John Wayne Cancer Center, specimen TCGA-W3-AA1R-06A (Metastatic).

[page 1 of 3]
CLINICAL HISTORY

Metastatic malignant melanoma. Primary right temporal melanoma Clark level IV, 3.6 mm., diagnosed :

ICD O-3
Melanoma NOS 8720/3
Site: Lymph nodes of head
face & neck (970
9) 4/2/14

GROSS DESCRIPTION

Specimens dictated in order received.

1. Labeled "anterior right neck dissection, including jugular digastric and submaxillary glands and end of parotid, double stitch at jugular vein": The specimen consists of a resection specimen including tan brown tumor. The specimen measures approximately 10.0 x 4.0 x 3.0 cm in maximal dimensions. The tumor has a pale brown appearance. It has a central defect consistent with prior tumor removal for specimen studies. The remaining tumor measures approximately 3.0 cm in diameter. Near the edge of the tumor, there is a double stitch marking jugular vein. The tumor is present at one end of the specimen, with the opposite end containing lobulated tan brown apparent salivary gland tissue. Nodes adjacent to the jugular vein are separately defected. The salivary gland tissue is grossly normal. Sections are embedded as follows: 1A-D - tumor, 1E and F - nodes adjacent to subclavian vein, 1G - soft tissue adjacent to subclavian vein, 1G-I salivary gland tissue, 1J additional lymph nodes, 1K - two bisected lymph nodes, 1L - remainder of lymph nodes.
3. Labeled "posterior triangle dissection": The specimen consists of a flat piece of fatty tissue bearing lymph nodes. It measures approximately 15.0 x 6.0 x 1.8 cm. A stitch is present at one end marking jugular subclavian junction. Lymph nodes are defected from the tissue and no gross tumor is identified. Tissue at the jugular subclavian junction is embedded as 3A and B. Other lymph nodes are embedded as 3C - 7 lymph nodes, 3D - 12 lymph nodes, 3E - 15 lymph nodes, 3F - 14 lymph nodes.
2. Labeled "right upper jugular node FS": The specimen consists of an ovoid gray pink apparent lymph node measuring 0.6 x 0.4 x 0.3 cm. It is bisected, showing no grossly evident tumor. All taken for frozen section diagnosis.

INTRAOPERATIVE CONSULTATION (FS): - No malignant cells identified.

[page 2 of 3]
- The remainder is embedded as ZSFA.

Microscopic sections are prepared and interpreted.

MICROSCOPIC

Histologic sections of the tumor nodule show predominantly necrotic malignancy with only a small focus of poorly differentiated malignant cells (slide 1C) consistent with metastatic melanoma. Although no lymph node tissue is identified in the main nodule, the appearance is consistent with an effaced lymph node, overrun with tumor with tumor extending into soft tissue. All remaining lymph nodes are negative for malignancy. A microfocus of granulomatous inflammation is noted in one of the posterior triangle lymph node (3B). Special stains for microorganisms (including AFB for acid fast bacilli and GMS for fungal/yeast organisms are pending).

DIAGNOSIS

1. LABELED "ANTERIOR RIGHT NECK DISSECTION, INCLUDING JUGULODIGASTRIC TISSUE, SUBMAXILLARY GLAND AND END OF PAROTID".
- METASTATIC MELANOMA NODULE, LARGELY NECROTIC, APPROXIMATELY 3.0 CM IN DIAMETER, CONSISTENT WITH A REPLACED LYMPH NODE.
- ALL REMAINING LYMPH NODES ARE NEGATIVE FOR MALIGNANCY (ONE POSITIVE OF SIXTEEN TOTAL).
- SALIVARY GLAND TISSUE SHOWS NO APPARENT ABNORMALITY.
2. LABELED "RIGHT UPPER JUGULAR LYMPH NODE".
- SINGLE BENIGN LYMPH NODE.
3. LABELED "POSTERIOR TRIANGLE DISSECTION".
- ALL LYMPH NODES ARE NEGATIVE FOR MALIGNANCY (45).
- ONE LYMPH NODE CONTAINS A FEW NON NECROTIZING GRANULOMAS; AFB AND GMS STAINS ARE PENDING.

ADDENDUM

** ADDENDUM NO.1 **

The GMS and AFB stains on the left posterior triangle lymph node containing non necrotizing granulomas have been performed. These stains are negative for acid fast bacilli and fungal/yeast organisms. Further clinical correlation is recommended to determine the significance of this finding.

Signed Electronically signed by:

[page 3 of 3]
** END OF REPORT **

Source: NCI Genomic Data Commons file 0d1184da-9bf5-4655-bb3f-1f40324b8fff (TCGA-W3-AA1R.48FB04ED-BA44-4AFD-AB10-E88175624ABD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).